Somatic mutation profile of tumor specimen C3L-01836-03 (aliquot CPT0086880009) from CPTAC case C3L-01836, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 47.1 years (17,215 days).
Specimen C3L-01836-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04df3acd-5502-4448-bc4d-ad5409cb6702.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01836-31 (Blood Derived Normal), aliquot CPT0087440002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd1881d9-cb8d-44d0-8231-b9f2452f3cde

The open-access MAF lists 21 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 5, Nonsense Mutation 2, Intron 2, 5'UTR 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- INHBE | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.069); catalogued as rs372615182; called by muse, mutect2, varscan2
- PBRM1 | c.4759C>T p.Q1587* (on ENST00000296302 / NM_001366071.2; = p.Q1480* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 4/15 reads (27%) | catalogued as COSV56302844; called by muse, mutect2, varscan2
- SUN5 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs376507648; called by mutect2, varscan2
- AGTRAP | c.143G>C p.R48P | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ATIC | c.1297G>A p.V433M | Missense Mutation (SNP) | VAF 68/416 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- KLHL30 | c.896_898del p.N299del | In Frame Del (DEL) | VAF 9/62 reads (15%) | called by pindel, varscan2
- LYST | c.10406G>T p.W3469L | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- NEURL1B | c.240G>T p.E80D | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH17 | c.2169G>A p.M723I | Missense Mutation (SNP) | VAF 63/409 reads (15%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SYNE2 | c.17918T>G p.L5973* | Nonsense Mutation (SNP) | VAF 24/324 reads (7%) | called by muse, mutect2
- VHL | c.168_169dup p.G57Afs*11 | Frame Shift Ins (INS) | VAF 38/250 reads (15%) | called by mutect2, pindel, varscan2
- ZNF324 | c.234C>A p.N78K | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DCAF8L1 | c.141G>A p.S47= | Silent (SNP) | VAF 49/154 reads (32%) | catalogued as rs760112871, COSV101491428, COSV101491459; called by muse, mutect2, varscan2
- PHLDB3 | c.1503C>T p.P501= | Silent (SNP) | VAF 32/119 reads (27%) | catalogued as rs1210066990; called by muse, mutect2, varscan2
- SPAG1 | c.1774C>T p.L592= | Silent (SNP) | VAF 24/260 reads (9%) | called by muse, mutect2
- ZNF227 | c.585T>A p.I195= | Silent (SNP) | VAF 41/206 reads (20%) | called by muse, mutect2, varscan2
- ZNF721 | c.762A>G p.K254= (on ENST00000338977; = p.K266= on NM_133474.4) | Silent (SNP) | VAF 36/242 reads (15%) | catalogued as rs781912933; called by muse, mutect2, varscan2
- CUBN | c.-37G>A | 5'UTR (SNP) | VAF 55/274 reads (20%) | called by muse, mutect2, varscan2
- DNM1L | c.1540-40del | Intron (DEL) | VAF 24/154 reads (16%) | called by mutect2, pindel, varscan2
- FSTL1 | c.331+106C>A | Intron (SNP) | VAF 52/329 reads (16%) | called by muse, mutect2, varscan2
- ZNF417 | c.-25G>A | 5'UTR (SNP) | VAF 35/228 reads (15%) | catalogued as rs773481811; called by muse, mutect2, varscan2
